Somatic mutation profile of tumor specimen TARGET-30-PALIIN-01A (aliquot TARGET-30-PALIIN-01A-01W) from TARGET case TARGET-30-PALIIN, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 3.5 years (1,279 days).
Specimen TARGET-30-PALIIN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0608c34-af7e-4ab1-9ae1-38a4945697db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALIIN-10A (Blood Derived Normal), aliquot TARGET-30-PALIIN-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/014995e8-a0b6-413d-90c7-7f23e4eef15a

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 20, Silent 8, Nonsense Mutation 3, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFMID | c.671A>T p.Q224L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV59976051; called by muse, mutect2, varscan2
- ANO3 | c.1560G>T p.K520N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV56790531; called by muse, mutect2, varscan2
- CCDC93 | c.416G>C p.R139P | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60121164; called by muse, mutect2, varscan2
- CSN1S1 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV55890493; called by muse, mutect2
- DISP3 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.03); catalogued as COSV53826763; called by muse, mutect2, varscan2
- DKK2 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 78/531 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV53393425, COSV53397814; called by muse, mutect2, varscan2
- F5 | c.4375G>T p.D1459Y | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63123687, COSV63129999; called by muse, mutect2, varscan2
- FRAS1 | c.10398C>A p.D3466E | Missense Mutation (SNP) | VAF 178/459 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53608649; called by muse, mutect2, varscan2
- GRIN2B | c.829C>A p.L277I | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.357); catalogued as COSV74205963; called by muse, mutect2
- HARBI1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as COSV56319258; called by muse, mutect2, varscan2
- IGSF21 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773303751, COSV52125659; called by muse, mutect2, varscan2
- ITGA3 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50310714; called by muse, mutect2, varscan2
- ITIH5 | c.1687G>T p.G563* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV53663846; called by muse, mutect2, varscan2
- RNASE12 | c.180C>A p.H60Q | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.243); catalogued as COSV60087573; called by muse, mutect2, varscan2
- SGO1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as rs200607145; called by muse, mutect2, varscan2
- SLC13A5 | c.1387A>G p.T463A | Missense Mutation (SNP) | VAF 169/814 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.268); catalogued as COSV53423032; called by muse, mutect2, varscan2
- SLC5A1 | c.172T>C p.F58L | Missense Mutation (SNP) | VAF 191/484 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV56685228; called by muse, mutect2, varscan2
- TMEM43 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60145978; called by muse, mutect2, varscan2
- UNC5D | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs753133707, COSV54792413; called by muse, mutect2, varscan2
- IKZF3 | c.1356T>A p.Y452* | Nonsense Mutation (SNP) | VAF 134/425 reads (32%) | called by muse, varscan2
- INSL5 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2
- LCORL | c.274dup p.C92Lfs*2 | Frame Shift Ins (INS) | VAF 34/106 reads (32%) | called by mutect2, pindel, varscan2
- PRAMEF4 | c.228T>A p.C76* | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- PTCHD1 | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.005); called by muse, mutect2
- SSPN | c.718del p.Q240Sfs*15 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- CHST9 | c.1101A>G p.V367= | Silent (SNP) | VAF 99/325 reads (30%) | catalogued as COSV52436650; called by muse, mutect2, varscan2
- DAB2 | c.135C>T p.G45= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as rs758227666, COSV57914254; called by muse, mutect2, varscan2
- ERN1 | c.2808C>G p.R936= | Silent (SNP) | VAF 34/220 reads (15%) | catalogued as COSV70502061; called by muse, mutect2, varscan2
- IPPK | c.711G>T p.L237= | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as COSV55333754; called by muse, mutect2, varscan2
- MUSK | c.249C>G p.L83= | Silent (SNP) | VAF 250/602 reads (42%) | catalogued as COSV51885476; called by muse, mutect2, varscan2
- OLFML2A | c.1866C>T p.Y622= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV56583286; called by muse, mutect2, varscan2
- SUSD3 | c.171C>T p.L57= | Silent (SNP) | VAF 61/185 reads (33%) | catalogued as rs746959146, COSV64937218; called by muse, mutect2, varscan2
- VCAM1 | c.1614C>T p.G538= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV54119243; called by muse, mutect2, varscan2
